Gene-level copy-number profile of tumor specimen C3N-01823-02 from CPTAC case C3N-01823, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 63.9 years (23,322 days).
Specimen C3N-01823-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f65c710f-f22f-496c-886b-7f893d15ac45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01823-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/cd93d84d-4f48-4cc5-b58b-2dad69ba6387

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 8,811; copy number 2: 35,718; copy number 3: 11,146; copy number 4: 1,955; copy number 5: 531; copy number 6: 138; copy number 7: 14; copy number 8: 37; copy number 10: 33; copy number 11: 6; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,890,314–42,213,918, 8 genes: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3.
- chr9:64,765,054–64,836,341, 3 genes: IGKV1OR-2, BNIP3P4, AL359955.1.
- chr13:110,809,676–110,813,084, 1 gene: LINC00567.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 761 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,001,606–164,831,480, 4 genes, copy number 5: AC084017.1, MIR1263, LINC01323, LINC01324.
- chr5:50,396,192–50,443,248, 1 gene, copy number 5: EMB.
- chr5:60,596,912–61,232,040, 13 genes, copy number 6 (within-gene range 4–6): DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1.
- chr6:34,889,255–40,587,364, 127 genes, copy number 5 (broad region; genes not listed).
- chr12:17,383,352–32,383,633, 257 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:41,188,320–41,932,592, 7 genes, copy number 5 (within-gene range 4–5): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1.
- chr12:43,835,967–45,445,438, 17 genes, copy number 5: TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1.
- chr12:69,326,574–69,460,724, 7 genes, copy number 6: AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373.
- chr14:32,934,396–35,113,130, 29 genes, copy number 5 (within-gene range 3–5): NPAS3, AL161851.1, AL161851.2, EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1.
- chr14:35,086,035–35,088,059, 1 gene, copy number 5 (within-gene range 3–5): AL049776.1.
- chr14:35,122,549–35,317,474, 1 gene, copy number 5 (within-gene range 3–5): AL121594.1.
- chr14:35,235,180–38,371,338, 63 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr14:45,891,087–53,883,740, 139 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr14:53,991,101–55,456,726, 31 genes, copy number 5: ATP5F1CP1, CDKN3, CNIH1, AL359792.1, GMFB, CGRRF1, SAMD4A, AL133444.1, GCH1, RNU6ATAC9P, MIR4308, FDPSP3, WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6.
- chr14:56,303,490–57,493,867, 24 genes, copy number 5: AL355073.1, AL355073.2, LINC02284, TMEM260, AL355103.1, AL161757.2, AL161757.5, AL161757.1, AL161757.3, OTX2, OTX2-AS1, AL161757.4, RN7SL461P, RNU6-1204P, AL137100.3, RPL3P3, AL137100.1, AL137100.2, AL391152.1, EXOC5, AP5M1, AL355834.1, NAA30, CCDC198.
- chr14:58,244,843–60,169,133, 34 genes, copy number 5 (within-gene range 3–5): PSMA3, AL132989.1, PSMA3-AS1, HMGB1P14, LINC00216, RNU6-341P, ARID4A, AL139021.2, TOMM20L, AL139021.1, TIMM9, KIAA0586, Y_RNA, HSBP1P1, HNRNPCP1, RPL9P5, DACT1, LINC01500, AL049873.1, AL049873.2, AKR1B1P5, PPIAP5, DAAM1, GPR135, L3HYPDH, AL121694.1, JKAMP, CCDC175, RTN1, MIR5586, AL133299.1, LRRC9, AL157911.1, PCNX4.
- chr14:67,189,393–67,336,061, 4 genes, copy number 5 (within-gene range 1–5): FAM71D, SF3B4P1, MPP5, AL135978.1.
- chr16:32,877,469–32,888,874, 2 genes, copy number 19: SLC6A10P, AC142086.1.

Autosomal genes at a single copy (total copy number 1): 6,471. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
